Somatic mutation profile of tumor specimen SM-JU32R (aliquot 7316UP-1766) from CPTAC case C383391, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Temporal lobe; Tumor grade: G3.
Specimen SM-JU32R: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b48f0b7c-5b79-48b4-a4d5-0322a2af24e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105272 (Blood Derived Normal), aliquot 7316UP-1108-1105272; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/700c95bb-13ff-4c81-adfd-908e67965043

The open-access MAF lists 100 somatic variants for this specimen: 58 protein-altering or splice-affecting, 30 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 30, Intron 6, Nonsense Mutation 3, Splice Site 2, RNA 2, 5'UTR 2, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAIN1 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.062); catalogued as rs745657091, COSV71420513; called by muse, mutect2, varscan2
- ARHGAP44 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs367607261; called by muse, mutect2, varscan2
- ASB7 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1440962022; called by muse, mutect2
- ASCC3 | c.1522A>G p.I508V | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.208); catalogued as rs748219576; called by muse, mutect2
- B4GALT7 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99219177; called by muse, mutect2
- BMP10 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs144469983; called by muse, mutect2, varscan2
- CHAT | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs779668516, COSV60334873; called by muse, mutect2, varscan2
- CILP2 | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs746090290; called by muse, mutect2
- COL6A5 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs374168010; called by muse, mutect2, varscan2
- FAT1 | c.7556G>A p.G2519E | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs550477464; called by muse, mutect2, varscan2
- FRMPD4 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66223539; called by muse, mutect2, varscan2
- KRT1 | c.1894G>A p.V632M | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.44); catalogued as rs532003323, COSV52868090; called by muse, mutect2
- KRTAP4-6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 67/551 reads (12%) | SIFT tolerated (0.13); catalogued as rs763253803, COSV61980902; called by muse, mutect2, varscan2
- MROH9 | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs889208046, COSV63015141; called by muse, mutect2, varscan2
- MYOD1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51456293; called by muse, mutect2, varscan2
- PLEKHG4B | c.3025T>C p.F1009L (on ENST00000283426; = p.F1365L on NM_052909.5) | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1479490320; called by muse, mutect2, varscan2
- PNKD | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs756863425, COSV51231403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTH2R | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs753279962, COSV55915312; called by muse, mutect2, varscan2
- RBFOX1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376377058; called by muse, mutect2, varscan2
- RELN | c.9904G>A p.A3302T | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs776769644, COSV59040921; called by muse, mutect2
- RELN | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 65/500 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759711654, COSV59024775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL5 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100240435; called by muse, mutect2, varscan2
- TUBA3C | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as rs923497577, COSV67139620; called by muse, mutect2, varscan2
- XKR3 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 29/196 reads (15%) | catalogued as rs562118958; called by muse, mutect2, varscan2
- ANKRD34C | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2
- ASH1L | c.1039G>C p.V347L | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); called by muse, mutect2
- CAGE1 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- CASZ1 | c.5123A>T p.E1708V | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.335); called by muse, mutect2
- CCDC71 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD96 | c.1480A>G p.T494A (on ENST00000283285 / NM_198196.3; = p.T478A on NM_005816.5) | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CFAP94 | c.919T>C p.S307P (on ENST00000320267 / NM_001352064.2; = p.S313P on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CLEC4G | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COL6A1 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 48/616 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CREBBP | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRTC2 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 80/586 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by mutect2, varscan2
- DDI2 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 29/226 reads (13%) | called by muse, mutect2, varscan2
- DLAT | c.1132A>C p.T378P | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- DSCAM | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2
- GOLGA7 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- GON4L | c.5030T>C p.I1677T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- MAB21L3 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- MYH13 | c.2028T>A p.C676* | Nonsense Mutation (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- NCL | c.1520A>C p.E507A | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); called by muse, mutect2
- NFATC1 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); called by muse, mutect2
- NOBOX | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCARE | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2
- PLXNC1 | c.2300+2T>A p.X767_splice | Splice Site (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- RAF1 | c.1370+2T>C p.X457_splice | Splice Site (SNP) | VAF 26/396 reads (7%) | called by muse, mutect2
- SPI1 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2
- SPRY1 | c.622T>C p.C208R | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- THADA | c.2371C>A p.L791I | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TMEM132C | c.2708A>G p.K903R | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFRSF21 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- TSC2 | c.4939T>C p.S1647P | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- URB1 | c.4417C>G p.P1473A | Missense Mutation (SNP) | VAF 33/389 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2
- YTHDF3 | c.98dup p.D33Efs*2 | Frame Shift Ins (INS) | VAF 19/163 reads (12%) | called by mutect2, pindel, varscan2
- ZNF212 | c.1464del p.G489Efs*38 | Frame Shift Del (DEL) | VAF 11/113 reads (10%) | called by mutect2, pindel, varscan2
- ZNF629 | c.484T>C p.W162R | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAM29 | c.612C>T p.V204= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs114696296, COSV63668865; called by muse, mutect2
- ADNP2 | c.1104T>C p.N368= | Silent (SNP) | VAF 23/271 reads (8%) | called by muse, mutect2
- ARID1A | c.6057C>T p.H2019= | Silent (SNP) | VAF 32/223 reads (14%) | called by muse, mutect2, varscan2
- ARPC4 | c.114G>A p.V38= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as rs1482592313; called by muse, mutect2, varscan2
- CHRM2 | c.117C>T p.I39= | Silent (SNP) | VAF 38/443 reads (9%) | catalogued as rs755854009, COSV57773475; called by muse, mutect2
- CLSTN2 | c.2004C>T p.F668= | Silent (SNP) | VAF 43/203 reads (21%) | catalogued as rs778778245, COSV71720462; called by muse, mutect2, varscan2
- DLC1 | c.2967G>T p.G989= (on ENST00000276297 / NM_001348081.2; = p.G552= on NM_006094.5) | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs1563589459; called by muse, varscan2
- DLX3 | c.798G>A p.P266= | Silent (SNP) | VAF 46/340 reads (14%) | catalogued as rs569475772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYSL2 | c.645G>T p.L215= | Silent (SNP) | VAF 27/320 reads (8%) | called by muse, mutect2
- H2AC1 | c.174T>C p.Y58= | Silent (SNP) | VAF 26/228 reads (11%) | called by muse, mutect2, varscan2
- LCK | c.6C>A p.G2= | Silent (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- MYH7 | c.4740C>T p.D1580= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as rs201469051, COSV62516883; called by muse, mutect2, varscan2
- NDRG4 | c.654G>A p.T218= (on ENST00000570248 / NM_001378344.1; = p.T250= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 27/225 reads (12%) | catalogued as rs781381338, COSV99262394; called by muse, mutect2, varscan2
- OR2AK2 | c.99C>G p.T33= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV63554593; called by muse, mutect2, varscan2
- OR5AU1 | c.267G>A p.R89= | Silent (SNP) | VAF 31/318 reads (10%) | catalogued as rs779575360; called by muse, mutect2, varscan2
- PAPSS1 | c.888T>A p.L296= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- PRDM16 | c.2667G>A p.P889= | Silent (SNP) | VAF 15/177 reads (8%) | catalogued as rs774537766; ClinVar: likely benign; called by muse, mutect2
- SH2B1 | c.27C>T p.D9= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs772157677; called by muse, mutect2
- SLC30A3 | c.933G>A p.S311= | Silent (SNP) | VAF 42/299 reads (14%) | catalogued as rs538009364, COSV99273777, COSV99273918; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A14 | c.726G>A p.A242= | Silent (SNP) | VAF 30/223 reads (13%) | catalogued as rs752901596, COSV51580118; called by muse, mutect2, varscan2
- SLCO1C1 | c.933C>T p.S311= | Silent (SNP) | VAF 17/223 reads (8%) | catalogued as COSV56868698, COSV56874989; called by muse, mutect2
- TANC1 | c.600C>T p.S200= | Silent (SNP) | VAF 38/310 reads (12%) | catalogued as rs1362556739; called by muse, mutect2, varscan2
- TOP2A | c.927G>A p.Q309= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs1403734143; called by muse, mutect2, varscan2
- TRIP12 | c.5088G>A p.K1696= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- UNC13C | c.4164C>A p.V1388= | Silent (SNP) | VAF 24/188 reads (13%) | called by muse, mutect2, varscan2
- UROD | c.561T>A p.A187= | Silent (SNP) | VAF 32/488 reads (7%) | called by muse, mutect2
- USH2A | c.7029G>A p.R2343= | Silent (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- USH2A | c.6579C>T p.I2193= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as rs765566223; called by muse, mutect2, varscan2
- ZAN | c.4158C>T p.C1386= | Silent (SNP) | VAF 23/259 reads (9%) | catalogued as rs376999914; called by muse, mutect2
- ZNF644 | c.2062C>A p.R688= | Silent (SNP) | VAF 39/662 reads (6%) | called by muse, mutect2
- ADAM6 | n.719G>A | RNA (SNP) | VAF 16/243 reads (7%) | catalogued as rs1555411042; called by muse, mutect2
- AGR2 | c.478+15C>G | Intron (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- CLCN6 | c.2529+70C>T | Intron (SNP) | VAF 29/451 reads (6%) | catalogued as rs755454276; called by muse, mutect2
- COL16A1 | c.4101+30A>G | Intron (SNP) | VAF 32/507 reads (6%) | called by muse, mutect2
- DUX4L8 | n.706C>T | RNA (SNP) | VAF 22/768 reads (3%) | catalogued as rs782032535; called by muse, mutect2
- GABBR1 | c.476-60G>T | Intron (SNP) | VAF 46/305 reads (15%) | catalogued as rs1347490372; called by muse, mutect2, varscan2
- HYPK | c.-764C>T | 5'UTR (SNP) | VAF 41/291 reads (14%) | catalogued as rs756657635; called by muse, mutect2, varscan2
- LILRA5 | c.-44T>A | 5'UTR (SNP) | VAF 40/175 reads (23%) | catalogued as rs1380637405; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185103C>T | Intron (SNP) | VAF 14/287 reads (5%) | called by muse, mutect2
- RN7SL545P | chr15:22431975 G>A | 5'Flank (SNP) | VAF 22/394 reads (6%) | catalogued as rs544394310; called by muse, mutect2
- SHH | c.*2729C>G | 3'UTR (SNP) | VAF 19/345 reads (6%) | catalogued as rs553158506; called by muse, mutect2
- STAT1 | c.1348-16C>A | Intron (SNP) | VAF 15/396 reads (4%) | called by muse, mutect2
